Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4341, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4341-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Bilateral renal tumors CR1.

Specimens Submitted:

1: SP: Left kidney

DIAGNOSIS:

- 1) KIDNEY, LEFT; TOTAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 7.3 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS ARTERIOSCLEROSIS AND MILD INTERSTITIAL CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- [REDACTED]
- [REDACTED]

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney" and consists of a total nephrectomy specimen measuring 17.0 x 11.0 x 6.0 cm. The specimen is bivalved to reveal a 7.3 x 7.0 x 4.0 cm well-circumscribed mass present in the upper pole of the kidney. This mass has a heterogeneous cut surface ranging from dark-yellow to orange to areas of tan-white myxoid appearance. No hemorrhage or cystic change are seen. The hyalinized and myxoid areas represent around 60% of the tumor cut surface. The tumor is overall confined to the kidney and has pushing borders with focal extension into the perirenal fat. The tumor abuts the renal pelvis without infiltration it. There is no infiltration or involvement of the renal vein by the tumor. The non-neoplastic kidney is unremarkable. No other gross lesions are identifiable. No adrenal gland is identified. Representative sections are submitted. Tissue is given for TPS. Photographs are taken.

Summary of Sections:

HM - margins of the ureter and vascular structures of the hilum

MM - soft lesion overlying the tumor

TS - tumor, sections of the more solid areas

TM - section of tumor of the myxoid hyalinized area

TP - sections of the tumor and adjacent renal pelvis

TF - sections of the tumor with perirenal fat

NK - non-neoplastic kidney

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: SP: Left kidney

Block	Sect. Site	PCs
1	HM	5
2	MM	2
1	NK	1
2	TF	2
2	TM	2
1	TP	1
4	TS	4

Source: NCI Genomic Data Commons file 93e29241-a231-4420-8293-a32441c3a4ee (TCGA-BP-4341.6898D581-8ACA-41EB-AC0E-6045A5089861.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).